Gene-level copy-number profile of tumor specimen TCGA-HU-A4GH-01A from TCGA case TCGA-HU-A4GH, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 75.2 years (27,473 days).
Specimen TCGA-HU-A4GH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.5f7cece6-0700-4874-8fa7-71e2b99e5cca.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HU-A4GH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fcef3863-2829-4818-ab91-3356dc9117be

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 220; copy number 2: 21,117; copy number 3: 15,131; copy number 4: 18,694; copy number 5: 2,619; copy number 6: 404; copy number 7: 802; copy number 8: 743; copy number 9: 8; copy number 12: 30; copy number 18: 16; copy number 19: 7; copy number 26: 5; copy number 36: 3; copy number 68: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HU-A4GH-01A-11D-A24C-01): tumor purity 0.75, ploidy 2.84, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:2,227,803–2,230,261, 1 gene: AL035693.1.
- chr6:2,341,450–2,386,110, 2 genes (within-gene range 0–2): HMGN2P28, AL031768.2.
- chr9:9,799,423–9,803,784, 1 gene: AL513422.1.
- chr16:6,873,899–6,874,005, 1 gene: RNU6-457P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,648 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:17,539,698–24,086,799, 176 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:143,343,180–191,228,467, 1,379 genes, copy number 6–8 (broad region; genes not listed).
- chr1:203,318,996–203,508,949, 6 genes, copy number 8: RNU6-487P, FMOD, AL359837.1, LARP7P1, PRELP, OPTC.
- chr1:213,492,288–213,794,587, 2 genes, copy number 5 (within-gene range 3–5): AL592402.1, AC096639.1.
- chr1:234,527,887–248,919,946, 350 genes, copy number 5–12 (broad region; genes not listed).
- chr2:28,307,063–28,751,722, 12 genes, copy number 5: AC093690.1, RPL23AP34, FLJ31356, FOSL2, AC104695.3, AC104695.2, AC104695.1, PLB1, SNRPGP7, AC074011.1, RNA5SP89, AC092164.1.
- chr2:43,027,823–43,233,394, 9 genes, copy number 6: LINC01819, LINC02590, RNU6-242P, LINC02580, AC010883.2, AC010883.3, ZFP36L2, LINC01126, AC010883.1.
- chr2:94,991,880–111,120,610, 369 genes, copy number 5 (broad region; genes not listed).
- chr2:111,098,345–111,168,445, 2 genes, copy number 5: ACOXL-AS1, BCL2L11.
- chr4:49,096–38,385,759, 558 genes, copy number 5–7 (broad region; genes not listed).
- chr4:76,708,853–77,076,309, 8 genes, copy number 7 (within-gene range 4–7): SHROOM3-AS1, AC107072.1, AC104687.2, AC104687.1, SOWAHB, SEPTIN11, TXNP6, CCNI.
- chr4:102,251,041–102,760,994, 12 genes, copy number 5: SLC39A8, RN7SL728P, AC098487.1, AF213884.2, AF213884.3, NFKB1, MANBA, AF213884.1, LRRC37A15P, KRT8P46, AC018797.1, AC018797.2.
- chr4:102,814,252–102,819,881, 1 gene, copy number 5: AC018797.3.
- chr4:183,099,257–183,517,527, 11 genes, copy number 6 (within-gene range 3–6): WWC2, WWC2-AS1, CLDN22, CLDN24, AC093844.1, AC112698.1, CDKN2AIP, VTI1BP2, AC107214.1, ING2, AC107214.2.
- chr6:132,518,830–132,817,564, 23 genes, copy number 6: RPL21P66, TAAR9, TAAR8, TAAR7P, TAAR6, TAAR5, TAAR4P, AL513524.1, TAAR3P, TAAR2, TAAR1, HLFP1, VNN1, CCNG1P1, VNN3, VNN2, AL032821.1, RBM11P1, SLC18B1, RPS12, SNORD101, SNORD100, SNORA33.
- chr6:146,598,967–170,738,536, 429 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr9:33,166,948–33,410,553, 9 genes, copy number 6: B4GALT1-AS1, RNU4ATAC15P, SPINK4, BAG1, CHMP5, NFX1, Y_RNA, AQP7, AL356218.2.
- chr10:44,712–38,783,108, 675 genes, copy number 5 (broad region; genes not listed).
- chr11:74,454,841–74,467,729, 1 gene, copy number 6 (within-gene range 3–6): KCNE3.
- chr11:74,482,250–74,669,117, 6 genes, copy number 6–12 (within-gene range 2–69): CYCSP27, AP001372.4, LIPT2, AP001372.2, POLD3, RANP3.
- chr12:116,977,442–117,452,170, 7 genes, copy number 7 (within-gene range 2–7): AC127164.1, AC026368.1, TESC, TESC-AS1, FBXO21, NOS1, ELOCP32.
- chr14:61,529,128–61,658,696, 4 genes, copy number 7: AL355916.3, AL355916.2, LINC01303, AL355916.1.
- chr17:39,566,915–40,598,585, 55 genes, copy number 5–26: AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867, WIPF2, CDC6, RARA, AC080112.4, RARA-AS1, AC080112.3, GJD3, AC080112.1, PPIAP54, RNA5SP441, AC080112.2, TOP2A, Y_RNA, RPL23AP75, IGFBP4, AC018629.1, TNS4, AC004585.1, CCR7, AC004585.2.
- chr18:49,431,744–50,195,147, 26 genes, copy number 6 (within-gene range 3–6): AC100778.1, AC100778.4, PRR13P4, C18orf32, RPL17-C18orf32, AC100778.2, AC100778.3, MIR1539, RPL17, SNORD58C, SNORD58A, SNORD58B, SRP72P1, LINC02837, LIPG, SMUG1P1, AC090227.3, ACAA2, AC090227.2, SNHG22, SCARNA17, AC090227.1, MYO5B, Y_RNA, RNA5SP457, AC091044.1.
- chr19:27,638,483–31,147,981, 70 genes, copy number 6–68 (broad region; genes not listed).
- chr19:31,167,457–31,225,143, 1 gene, copy number 19: LINC01791.
- chr20:87,250–1,491,587, 44 genes, copy number 5: DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1, TCF15, SRXN1, AL121758.1, SCRT2, SLC52A3, FAM110A, RPS10P5, ANGPT4, RSPO4, AL110114.1, PSMF1, ACTG1P3, TMEM74B, AL031665.1, C20orf202, RAD21L1, SNPH, SDCBP2, AL136531.2, AL136531.3, SDCBP2-AS1, AL136531.1, FKBP1A, MIR6869, NSFL1C, SIRPB2.
- chr20:49,794,811–64,313,132, 355 genes, copy number 5 (broad region; genes not listed).
- chr21:34,073,224–36,004,667, 28 genes, copy number 5 (within-gene range 3–5): MRPS6, SLC5A3, AP000317.2, RPS5P2, LINC00310, AP000317.1, AP000320.1, KCNE2, SMIM11A, FAM243A, AP000322.2, SMIM34A, AP000322.1, KCNE1, AP000324.1, RCAN1, CLIC6, LINC00160, LINC01426, RUNX1, AP000331.1, AF015262.1, RPL34P3, EZH2P1, AF015720.1, MIR802, RPS20P1, PPP1R2P2.
- chr21:41,464,300–42,143,453, 20 genes, copy number 5 (within-gene range 3–5): TMPRSS2, AP001610.1, AP001610.3, AP006748.1, PCSEAT, LINC00111, LINC00479, LINC00112, RIPK4, AP001615.1, MIR6814, PRDM15, AP001619.2, AP001619.1, AP001619.3, C2CD2, ZBTB21, ZNF295-AS1, UMODL1, UMODL1-AS1.

Autosomal genes at a single copy (total copy number 1): 216. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
